Somatic mutation profile of tumor specimen 1425a1a1-c835-47a2-a9b9-4db5d0 (aliquot 1425a1a1-c835-47a2-a9b9-4db5d0_D6) from CPTAC case 09CO011, project CPTAC-2 (Colon — Adenomas and Adenocarcinomas). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage I.
Specimen 1425a1a1-c835-47a2-a9b9-4db5d0: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d1043873-9b42-41fa-97bc-91b028a3df32.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 42f03c67-93e0-4c61-adeb-a0c82c (Blood Derived Normal), aliquot 42f03c67-93e0-4c61-adeb-a0c82c_D1_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2f5c7237-d936-46ce-82cb-a8ac911f1603

The open-access MAF lists 118 somatic variants for this specimen: 83 protein-altering or splice-affecting, 25 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 76, Silent 25, Nonsense Mutation 5, 5'UTR 4, Intron 3, 3'UTR 2, In Frame Ins 1, 5'Flank 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 120/303 reads (40%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SMC3 | c.2111T>C p.I704T | Missense Mutation (SNP) | VAF 48/86 reads (56%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.784); catalogued as rs1564794233; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCA2 | c.3439C>T p.R1147W (on ENST00000614293; = p.R1117W on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 172/432 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1195370052, COSV99687417; called by muse, mutect2, varscan2
- ACTL9 | c.1174G>A p.A392T | Missense Mutation (SNP) | VAF 88/233 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0.218); catalogued as rs1568430953, COSV61004535; called by muse, mutect2, varscan2
- ADGRV1 | c.7215A>C p.Q2405H | Missense Mutation (SNP) | VAF 10/182 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV101316515, COSV67988724; called by muse, mutect2
- AFDN | c.4651G>A p.A1551T | Missense Mutation (SNP) | VAF 89/296 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.572); catalogued as rs150082840; called by muse, mutect2, varscan2
- APC | c.2821G>T p.E941* | Nonsense Mutation (SNP) | VAF 115/393 reads (29%) | catalogued as CM105842, COSV57327519; called by muse, mutect2, varscan2
- APC | c.4438C>T p.Q1480* | Nonsense Mutation (SNP) | VAF 71/170 reads (42%) | catalogued as CM995160, COSV57334248, COSV99072999; called by muse, mutect2, varscan2
- ARMC1 | c.103G>A p.V35I | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.604); catalogued as rs774241744; called by muse, mutect2, varscan2
- BAIAP2L2 | c.1135G>A p.E379K | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs774819763; called by muse, mutect2, varscan2
- BTNL9 | c.773C>T p.A258V | Missense Mutation (SNP) | VAF 62/193 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.611); catalogued as rs1201056069; called by muse, mutect2, varscan2
- CA10 | c.380G>A p.R127Q | Missense Mutation (SNP) | VAF 52/118 reads (44%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.999); catalogued as rs1409313336, COSV99562393; called by muse, mutect2, varscan2
- CCDC60 | c.463C>T p.R155C | Missense Mutation (SNP) | VAF 57/198 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.034); catalogued as rs147505092; called by muse, mutect2, varscan2
- CHIA | c.55G>T p.G19C | Missense Mutation (SNP) | VAF 62/199 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV58475679; called by muse, mutect2, varscan2
- CHRNA4 | c.1430C>T p.A477V | Missense Mutation (SNP) | VAF 46/157 reads (29%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.007); catalogued as rs200243948, COSV100937524; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- COL6A1 | c.1226C>T p.A409V | Missense Mutation (SNP) | VAF 270/828 reads (33%) | SIFT tolerated (0.26); PolyPhen benign (0.102); catalogued as rs765826390, COSV62615268; called by muse, mutect2, varscan2
- DLGAP4 | c.640G>A p.E214K | Missense Mutation (SNP) | VAF 127/538 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.04); catalogued as rs760975376, COSV59414891; called by muse, mutect2, varscan2
- DMRTB1 | c.959C>A p.T320N | Missense Mutation (SNP) | VAF 91/333 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.676); catalogued as COSV65113973; called by muse, varscan2
- DPP9 | c.1089C>T p.Y363= (on ENST00000598800; = p.Y392= on NM_139159.5) | Splice Region (SNP) | VAF 18/68 reads (26%) | catalogued as rs557457810; called by muse, mutect2, varscan2
- ELMOD1 | c.562G>A p.A188T | Missense Mutation (SNP) | VAF 35/112 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.066); catalogued as rs752553992, COSV56191383; called by muse, mutect2, varscan2
- ERICH6 | c.1813C>T p.R605C | Missense Mutation (SNP) | VAF 80/164 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as rs370477652; called by muse, mutect2, varscan2
- FOXRED1 | c.1261G>A p.V421M | Missense Mutation (SNP) | VAF 176/526 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.743); catalogued as rs199542988, CM0911501, COSV55004875; called by muse, mutect2, varscan2
- GFPT2 | c.1847G>A p.R616H | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.124); catalogued as rs778999391, COSV99517536; called by muse, mutect2, varscan2
- GLP1R | c.1343C>T p.T448M | Missense Mutation (SNP) | VAF 48/186 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as rs961473826, COSV64716490; called by muse, mutect2, varscan2
- HEPACAM | c.346G>A p.D116N | Missense Mutation (SNP) | VAF 199/588 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201691514, COSV53432229; called by muse, mutect2, varscan2
- HGSNAT | c.259G>A p.V87I | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.011); catalogued as rs374287774; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- INKA1 | c.695G>A p.R232Q | Missense Mutation (SNP) | VAF 298/551 reads (54%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as rs575817542; called by muse, mutect2, varscan2
- LDHAL6B | c.974T>C p.I325T | Missense Mutation (SNP) | VAF 91/187 reads (49%) | SIFT tolerated (0.06); PolyPhen benign (0.026); catalogued as rs779180252; called by muse, mutect2, varscan2
- MAGEB4 | c.746T>C p.L249P | Missense Mutation (SNP) | VAF 35/388 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100974991; called by muse, mutect2
- MAN1C1 | c.572G>A p.R191H | Missense Mutation (SNP) | VAF 31/173 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs755018052, COSV56045358; called by muse, mutect2, varscan2
- MFN2 | c.1144G>T p.A382S | Missense Mutation (SNP) | VAF 248/795 reads (31%) | SIFT tolerated (0.43); PolyPhen benign (0.155); catalogued as CM132481; called by muse, mutect2, varscan2
- NDST4 | c.1623G>C p.Q541H | Missense Mutation (SNP) | VAF 6/112 reads (5%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs1181866592; called by muse, mutect2
- OSBPL6 | c.1283C>G p.S428C | Missense Mutation (SNP) | VAF 29/97 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs761301073; called by muse, mutect2, varscan2
- PDIA6 | c.152A>G p.Y51C | Missense Mutation (SNP) | VAF 23/39 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as rs756138282; called by muse, mutect2, varscan2
- PHKA2 | c.2635G>A p.E879K | Missense Mutation (SNP) | VAF 365/876 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.435); catalogued as rs761309363, COSV66052411; called by muse, mutect2, varscan2
- RPA4 | c.235G>A p.V79I | Missense Mutation (SNP) | VAF 151/385 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1437106087; called by muse, mutect2, varscan2
- SEC24C | c.793G>A p.G265R | Missense Mutation (SNP) | VAF 105/190 reads (55%) | SIFT deleterious (0.03); PolyPhen benign (0.258); catalogued as rs1259089620; called by muse, mutect2, varscan2
- SMAD9 | c.1282C>T p.R428C (on ENST00000379826 / NM_001127217.3; = p.R391C on NM_005905.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 180/408 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1286688113; called by muse, mutect2, varscan2
- ST8SIA5 | c.899G>T p.S300I | Missense Mutation (SNP) | VAF 208/476 reads (44%) | PolyPhen probably damaging (1); catalogued as COSV59334132; called by muse, mutect2, varscan2
- STXBP5L | c.390T>G p.S130R | Missense Mutation (SNP) | VAF 5/77 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.361); catalogued as COSV56502232, COSV56514489; called by muse, mutect2
- TECTA | c.6070G>A p.V2024I | Missense Mutation (SNP) | VAF 70/250 reads (28%) | SIFT tolerated (0.23); PolyPhen benign (0.403); catalogued as rs772595230, COSV99878765; called by muse, mutect2, varscan2
- TSHZ1 | c.3013C>G p.L1005V (on ENST00000580243 / NM_001308210.2; = p.L960V on NM_005786.6) | Missense Mutation (SNP) | VAF 17/218 reads (8%) | SIFT tolerated (0.82); PolyPhen benign (0.123); catalogued as COSV59012529; called by muse, mutect2
- ZDBF2 | c.4729T>A p.F1577I | Missense Mutation (SNP) | VAF 27/136 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0.021); catalogued as COSV65624690; called by muse, mutect2, varscan2
- ZNF521 | c.1043C>T p.T348M | Missense Mutation (SNP) | VAF 191/427 reads (45%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.765); catalogued as rs764521937, COSV100831245, COSV64126417; called by muse, mutect2, varscan2
- AHNAK | c.740C>A p.T247N | Missense Mutation (SNP) | VAF 159/456 reads (35%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- BTBD10 | c.1209G>A p.M403I | Missense Mutation (SNP) | VAF 107/383 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.491); called by muse, mutect2, varscan2
- CD207 | c.477T>A p.S159R | Missense Mutation (SNP) | VAF 49/159 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CFP | c.443G>A p.C148Y | Missense Mutation (SNP) | VAF 98/425 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- DCBLD2 | c.928G>C p.A310P | Missense Mutation (SNP) | VAF 69/159 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- DNAJC16 | c.265T>G p.Y89D | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); called by muse, mutect2, varscan2
- DND1 | c.245G>A p.G82D | Missense Mutation (SNP) | VAF 173/528 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- FASTK | c.1534C>T p.L512F | Missense Mutation (SNP) | VAF 14/374 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.007); called by muse, mutect2
- FMN2 | c.812A>C p.Q271P | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- FOXE1 | c.452G>A p.R151H | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- GLIS1 | c.215C>T p.P72L | Missense Mutation (SNP) | VAF 45/130 reads (35%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- GRHL2 | c.878T>C p.I293T | Missense Mutation (SNP) | VAF 135/377 reads (36%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.674); called by muse, mutect2, varscan2
- GRIK2 | c.1421T>G p.L474R | Missense Mutation (SNP) | VAF 18/224 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- H2AC20 | c.331A>C p.N111H | Missense Mutation (SNP) | VAF 55/157 reads (35%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- KCNH5 | c.551T>G p.V184G | Missense Mutation (SNP) | VAF 7/167 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.461); called by muse, mutect2
- KMT2C | c.14475C>A p.Y4825* | Nonsense Mutation (SNP) | VAF 9/162 reads (6%) | called by muse, mutect2
- L1TD1 | c.1222_1223insGGG p.E407_E408insG | In Frame Ins (INS) | VAF 10/67 reads (15%) | called by mutect2, pindel, varscan2
- LRRC9 | c.2725G>A p.E909K | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.16); PolyPhen benign (0.355); called by muse, mutect2, varscan2
- MEN1 | c.5G>A p.G2E | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- NT5C1B | c.643G>A p.A215T (on ENST00000359846 / NM_001199086.2; = p.A155T on NM_033253.4) | Missense Mutation (SNP) | VAF 92/362 reads (25%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- NTNG2 | c.928A>G p.N310D | Missense Mutation (SNP) | VAF 24/189 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.47); called by muse, mutect2, varscan2
- NUP210L | c.1789A>G p.K597E | Missense Mutation (SNP) | VAF 14/130 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.285); called by muse, mutect2
- OR10R2 | c.155T>G p.L52R | Missense Mutation (SNP) | VAF 12/264 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); called by muse, mutect2
- OR5T3 | c.331A>C p.T111P | Missense Mutation (SNP) | VAF 20/516 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.707); called by muse, mutect2
- OR8B3 | c.654T>A p.Y218* | Nonsense Mutation (SNP) | VAF 14/180 reads (8%) | called by muse, mutect2
- PJVK | c.910A>T p.I304F | Missense Mutation (SNP) | VAF 89/257 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.54); called by muse, mutect2, varscan2
- PURG | c.584T>A p.F195Y | Missense Mutation (SNP) | VAF 93/389 reads (24%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.516); called by muse, mutect2, varscan2
- REPS2 | c.190G>A p.A64T | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.37); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- RYR2 | c.8722A>C p.K2908Q | Missense Mutation (SNP) | VAF 44/166 reads (27%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- SCAF4 | c.1368G>T p.R456S | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.714); called by muse, mutect2, varscan2
- SCN5A | c.5945G>A p.R1982K (on ENST00000333535 / NM_198056.3; = p.R1981K on NM_000335.5) | Missense Mutation (SNP) | VAF 35/89 reads (39%) | SIFT tolerated (0.64); PolyPhen possibly damaging (0.689); called by mutect2, varscan2
- SLC4A10 | c.1005A>C p.L335F (on ENST00000446997 / NM_001354461.2; = p.L305F on NM_022058.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/102 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SMAD4 | c.136A>T p.K46* | Nonsense Mutation (SNP) | VAF 106/241 reads (44%) | called by muse, mutect2, varscan2
- TTC38 | c.388C>G p.L130V | Missense Mutation (SNP) | VAF 67/115 reads (58%) | SIFT tolerated (0.9); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- WFDC8 | c.461G>A p.C154Y | Missense Mutation (SNP) | VAF 55/210 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZBTB32 | c.273G>T p.R91S | Missense Mutation (SNP) | VAF 44/131 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ZMYND8 | c.2572G>C p.G858R | Missense Mutation (SNP) | VAF 68/154 reads (44%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.74); called by muse, mutect2, varscan2
- ZNF207 | c.1205T>G p.I402S | Missense Mutation (SNP) | VAF 50/103 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- ZSCAN2 | c.354T>A p.S118R | Missense Mutation (SNP) | VAF 8/195 reads (4%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.567); called by muse, mutect2
- AEBP1 | c.2520C>T p.T840= | Silent (SNP) | VAF 111/348 reads (32%) | catalogued as rs772412215; called by muse, mutect2, varscan2
- CLIP4 | c.909A>G p.G303= | Silent (SNP) | VAF 18/52 reads (35%) | called by muse, mutect2, varscan2
- CNTN3 | c.726T>G p.G242= | Silent (SNP) | VAF 4/42 reads (10%) | catalogued as COSV55161904, COSV99725440; called by muse, mutect2
- CSPG4 | c.5634C>T p.N1878= | Silent (SNP) | VAF 27/146 reads (18%) | catalogued as rs370088802; called by muse, mutect2, varscan2
- DENND2A | c.810G>A p.R270= | Silent (SNP) | VAF 71/281 reads (25%) | called by muse, mutect2, varscan2
- FERD3L | c.129C>T p.A43= | Silent (SNP) | VAF 83/459 reads (18%) | called by muse, mutect2, varscan2
- FEZF1 | c.813G>T p.A271= | Silent (SNP) | VAF 28/88 reads (32%) | catalogued as rs570653515, COSV100484587; called by muse, mutect2, varscan2
- GALNT17 | c.1479G>A p.P493= | Silent (SNP) | VAF 28/132 reads (21%) | catalogued as rs145007893; called by muse, mutect2, varscan2
- JHY | c.2151C>T p.Y717= | Silent (SNP) | VAF 38/113 reads (34%) | catalogued as rs150629469; called by muse, mutect2, varscan2
- LVRN | c.504C>T p.N168= | Silent (SNP) | VAF 234/724 reads (32%) | catalogued as rs752634994, COSV63497645; called by muse, mutect2, varscan2
- MBD1 | c.273G>A p.R91= | Silent (SNP) | VAF 58/881 reads (7%) | called by muse, mutect2
- NEB | c.11901T>C p.N3967= | Silent (SNP) | VAF 28/115 reads (24%) | called by muse, mutect2, varscan2
- OR1N1 | c.168C>T p.P56= | Silent (SNP) | VAF 24/212 reads (11%) | called by muse, mutect2, varscan2
- SERPINH1 | c.99G>A p.A33= | Silent (SNP) | VAF 226/800 reads (28%) | catalogued as rs767591495; called by muse, mutect2, varscan2
- SFTPD | c.6G>T p.L2= | Silent (SNP) | VAF 150/256 reads (59%) | called by muse, varscan2
- SHROOM3 | c.5442G>T p.L1814= | Silent (SNP) | VAF 80/441 reads (18%) | called by muse, mutect2, varscan2
- SLC22A7 | c.813C>A p.G271= (on ENST00000372585 / NM_153320.2; = p.G269= on NM_006672.3) | Silent (SNP) | VAF 44/182 reads (24%) | called by muse, mutect2, varscan2
- SSC5D | c.2598C>T p.D866= | Silent (SNP) | VAF 114/372 reads (31%) | catalogued as rs564827454; called by muse, mutect2, varscan2
- TAT | c.991C>T p.L331= | Silent (SNP) | VAF 22/532 reads (4%) | catalogued as COSV100587415; called by muse, mutect2
- TMEM108 | c.1407C>T p.I469= | Silent (SNP) | VAF 114/209 reads (55%) | catalogued as rs765970493; called by muse, mutect2, varscan2
- TRIM74 | c.696C>T p.F232= | Silent (SNP) | VAF 95/824 reads (12%) | catalogued as rs375247896; called by muse, mutect2, varscan2
- ZFHX3 | c.2964C>T p.L988= | Silent (SNP) | VAF 266/800 reads (33%) | called by muse, mutect2, varscan2
- ZMAT1 | c.1236T>C p.T412= | Silent (SNP) | VAF 32/448 reads (7%) | catalogued as COSV65658231; called by muse, mutect2
- ZNF208 | c.2625C>A p.T875= | Silent (SNP) | VAF 89/257 reads (35%) | called by muse, mutect2, varscan2
- ZNF530 | c.234C>T p.G78= | Silent (SNP) | VAF 18/191 reads (9%) | called by muse, mutect2
- APTX | c.*116T>C | 3'UTR (SNP) | VAF 123/276 reads (45%) | called by muse, mutect2, varscan2
- ARHGEF4 | chr2:130916290 C>T | 5'Flank (SNP) | VAF 61/164 reads (37%) | catalogued as rs577995267; called by muse, mutect2, varscan2
- CSF2RA | c.-61C>T | 5'UTR (SNP) | VAF 47/129 reads (36%) | called by muse, mutect2, varscan2
- DSPP | c.-7A>G | 5'UTR (SNP) | VAF 39/291 reads (13%) | called by muse, mutect2, varscan2
- FGF10 | c.-49G>T | 5'UTR (SNP) | VAF 88/295 reads (30%) | called by muse, mutect2, varscan2
- LSS | c.-20C>T | 5'UTR (SNP) | VAF 121/364 reads (33%) | catalogued as rs751723086; called by muse, mutect2, varscan2
- SDF4 | c.715+14C>T | Intron (SNP) | VAF 110/301 reads (37%) | called by muse, mutect2, varscan2
- TTLL10 | c.-28+1377G>A | Intron (SNP) | VAF 136/646 reads (21%) | catalogued as rs1276427350; called by mutect2, varscan2
- XIAP | c.*122dup | 3'UTR (INS) | VAF 50/204 reads (25%) | called by mutect2, varscan2
- ZNF451 | c.186+1621C>T | Intron (SNP) | VAF 46/157 reads (29%) | called by muse, mutect2, varscan2
